Surgical pathology report (de-identified scan), TCGA case TCGA-85-A5B5, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-A5B5-01A (Primary Tumor).

Gross Description: In the upper lobe bronchus there is a tumor with irregular shape and fibrous density which narrows bronchus lumen. Tumor size is 3x2.5x2.5 cm. There are nine black bronchopulmonal lymph nodes and five hilar lymph nodes, up to 0.3-1 cm in size. Separately there is a surgical margin.

Microscopic Description: Squamous cell carcinoma of the lung, G-3. Surgical margin and vessels are free of tumor elements. Examined lymph nodes are without signs of metastases.

Diagnosis Details: Tumor Features: Indeterminate, Tumor Extent: Localized, NOS , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: LUNG TISSUE CHECKLIST

Specimen type: Pneumonectomy

Tumor site: Lung

Tumor size: 2.5 x 2.5 x 3 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: 0/14 positive for metastasis (Bronchopulmonal, hilar 0/14)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Right- upper

ICD O-3
Carcinoma, Squamous Cell NOS
Site: (R) Lung, upper lobe
8070/3
C34.1
12/17/12 JAO

Source: NCI Genomic Data Commons file ac7f8148-e663-4543-8801-8b6c84a1d7b1 (TCGA-85-A5B5.DF0EBE84-145F-478E-8242-80A6B267F532.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).